Surgical pathology report (de-identified scan), TCGA case TCGA-D9-A1JX, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D9-A1JX-06A (Metastatic).

ICD-0-3

Melanoma, NOS 8720/3

Site: lymph node, inguinal C77.4

3/11/11
pw

page 1 / 1

Department of Cancer Pathology

copy No. 1

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: 1. Multiple organ resection – iliac lymph nodes (common)
2. Multiple organ resection – iliac lymph nodes (common)
3. Multiple organ resection – inguinal lymph nodes

Unit in charge: Cancer

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: up to 8 working days

Clinical diagnosis:

Examination performed on:

Examination result:

1/ Lymphonodulitis reactiva No III. Reactive lymphonodulitis No III

2/ Lymphonodulitis reactiva No II. Reactive lymphonodulitis No II

3/ Metastases melanomatis in lymphonodis (VII/XVI). Melanoma metastases in lymph nodes (VII/XVI)

Compliance validated by:

Source: NCI Genomic Data Commons file b4e4f099-e2ef-47d3-be60-de1622198b8c (TCGA-D9-A1JX.696460B6-BF6C-456E-873F-D99A95FEBFA0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).